TARGET case TARGET-52-PAVVIT — Rhabdoid Tumor (TARGET-RT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b9c15813-e490-5a30-9bca-fb19864cdcf0

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Malignant rhabdoid tumor: ICD-O-3 morphology code: 8963/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 4.3 years (1,555 days); Year of diagnosis: 2013; Days to last follow up: 1,292 days (3.5 years); Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, distant metastasis identified at diagnosis.
   Treatment given: Protocol identifier: AREN03B2.

Follow-up (2 entries)
- Days to follow up: 576 days (1.6 years); Days to first event: 576 days (1.6 years); First event: Relapse.
- Days to follow up: 1,292 days (3.5 years); Year of follow up: 2016.

Biospecimens (1 sample)
- Sample TARGET-52-PAVVIT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Supplement_20230322.xlsx, for sample TARGET-52-PAVVIT-01A-01D:
- Cohort: Validation
- Stage of the primary tumour at the time of diagnosis: 4
- Type of mutation in tumor: Still with disease in 2016

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1292
- Stage: III/IV
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: RT
